Gene-level copy-number profile of tumor specimen HTMCP-03-06-02120-01B from CGCI case HTMCP-03-06-02120, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2.
Specimen HTMCP-03-06-02120-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 92372dd4-8f2b-44dc-9b59-fd1dba63e4f2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02120-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,243 have no estimate.
https://portal.gdc.cancer.gov/files/06801e26-1ace-4e02-a562-b25cdf10942e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 32; copy number 2: 3,185; copy number 3: 24,126; copy number 4: 20,561; copy number 5: 5,429; copy number 6: 3,076; copy number 7: 1,406; copy number 8: 536; copy number 9: 2; copy number 10: 5; copy number 11: 4; copy number 14: 11; copy number 18: 1; copy number 19: 5.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:13,273,539–13,275,627, 1 gene: PRAMEF32P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,970 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:6,521,347–6,554,513, 3 genes, copy number 7: NOL9, RNU6-731P, AL591866.1.
- chr3:136,862,208–136,951,606, 2 genes, copy number 8 (within-gene range 6–8): NCK1, RAD51AP1P1.
- chr5:58,198–45,895,970, 679 genes, copy number 7–8 (broad region; genes not listed).
- chr9:39,886,861–39,892,895, 3 genes, copy number 14: RN7SL763P, SNORA70, CR769767.1.
- chr9:39,983,821–39,984,401, 1 gene, copy number 14: RPL7AP49.
- chr9:60,914,407–60,964,196, 5 genes, copy number 14: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3.
- chr14:21,941,128–22,482,959, 58 genes, copy number 7 (within-gene range 6–7): TRAV9-2, TRAV15, AC245505.1, TRAV12-3, TRAV8-6, TRAV16, TRAV17, TRAV18, TRAV19, AC245505.2, TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54.
- chr14:22,547,506–22,552,156, 1 gene, copy number 7: TRAC.
- chr14:60,639,216–60,658,259, 2 genes, copy number 8: SALRNA1, SIX1.
- chr14:77,652,827–77,653,055, 1 gene, copy number 7: COX6CP11.
- chr15:21,019,388–21,103,138, 4 genes, copy number 9–19: FAM30C, AC037471.1, BCAR1P2, RN7SL400P.
- chr15:32,394,365–32,439,767, 5 genes, copy number 10: RN7SL185P, AC135983.1, ULK4P1, U8, DNM1P32.
- chr17:19,092,974–19,214,045, 8 genes, copy number 11–19: AC007952.2, AC007952.4, SNORD3D, SNORD3D, SNORD3A, SNORD3C, AC106017.1, KYNUP3.
- chr20:2,380,901–61,940,617, 1,194 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr21:44,107,373–44,210,114, 3 genes, copy number 7–18 (within-gene range 3–18): PWP2, GATD3A, LINC01678.
- chr21:44,200,602–44,207,399, 1 gene, copy number 9: AP001057.1.

Autosomal genes at a single copy (total copy number 1): 32. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
